Gene-level copy-number profile of tumor specimen MP2PRT-PANWDL-TMP1-A from MP2PRT case MP2PRT-PANWDL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Blastic plasmacytoid dendritic cell neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PANWDL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 448b0016-641e-4452-9e04-daf75e0cc760.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANWDL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/d8f7efdb-bd0f-4560-84a7-a6615632dade

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,037; copy number 2: 55,857.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 3 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A.
- chr2:89,947,512–89,960,754, 2 genes: IGKV2D-29, IGKV2D-28.
- chr2:90,004,797–90,005,629, 1 gene: IGKV2D-24.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
